TARGET case TARGET-15-SJMPAL043506 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2ecfcab8-9437-409a-ba4f-dafb8258e774

Demographics
Sex at birth: male; Age at index: 6 years; Vital status: Dead; Days to death: 769 days (2.1 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 6.1 years (2,218 days); Year of diagnosis: 2002; Days to last follow up: 769 days (2.1 years).

Follow-up (1 entry)
- Days to follow up: 769 days (2.1 years); First event: Relapse; Year of follow up: 2004.

Biospecimens (3 samples)
- Samples TARGET-15-SJMPAL043506-04A, TARGET-15-SJMPAL043506-04B (2 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL043506-14A.1: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 769
- Protocol: St. Jude
- Karyotype: 46,XY,dup(1)(q32q21)[10]/47,idem,add(5)(q31),del(6)(q13q23),+mar[7]/46,XY[3]
- WHO ALAL Classification: B/M
- WHO Dx: B-ALL
- WHO RL1: ALL
- WHO RL2: B/M
